Gene-level copy-number profile of tumor specimen TCGA-DX-AB32-01A from TCGA case TCGA-DX-AB32, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 51.0 years (18,631 days).
Specimen TCGA-DX-AB32-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f31af923-2fe0-48c9-b19b-7720edc23f72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB32-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01c52f3c-460a-41b5-b203-e24c4d5df48e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 22,110; copy number 2: 36,978; copy number 3: 538; copy number 4: 4; copy number 5: 1; copy number 10: 6; copy number 12: 128; copy number 14: 14; copy number 18: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB32-01A-11D-A416-01): tumor purity 0.56, ploidy 1.7, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:53,433,977–53,703,938, 9 genes (within-gene range 0–1): RBL2, RNU6-1153P, AC007342.1, AC007342.6, AC007342.7, AKTIP, AC007497.2, RPGRIP1L, AC007497.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 169 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,814,294–7,790,482, 26 genes, copy number 5–14 (within-gene range 1–14): AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1.
- chr3:11,790,442–15,142,157, 72 genes, copy number 12 (broad region; genes not listed).
- chr3:80,163,327–90,261,708, 71 genes, copy number 10–18 (within-gene range 2–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
